Gene-level copy-number profile of tumor specimen ALCH-AEJ9-TTP1-A from ALCHEMIST case ALCH-AEJ9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.7 years (21,815 days).
Specimen ALCH-AEJ9-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c66aaf2c-a397-45a0-8be2-9823e4ceb0f4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEJ9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/1fe80434-e3da-4110-8336-d0bb8a3bdf19

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 89; copy number 1: 14,808; copy number 2: 38,372; copy number 3: 4,546; copy number 4: 1,046; copy number 5: 48.

Homozygous deletions (total copy number 0; autosomes only): 81 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,014,028–16,019,594, 1 gene (within-gene range 0–1): HSPB7.
- chr2:127,048,027–127,107,288, 1 gene: BIN1.
- chr2:232,442,034–232,447,418, 1 gene: DIS3L2P1.
- chr5:135,038,831–135,040,047, 1 gene (within-gene range 0–2): C5orf66-AS1.
- chr7:64,104,093–64,112,572, 9 genes (within-gene range 0–2): MTND4P2, MTND4LP2, MTND3P2, MTCO3P8, MTATP6P18, MTCO2P8, MTCO1P8, MTND2P4, MTND1P2.
- chr7:149,776,042–149,833,979, 1 gene: SSPOP.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr11:2,840,135–2,861,568, 1 gene (within-gene range 0–2): KCNQ1-AS1.
- chr11:67,266,473–67,286,556, 1 gene: GRK2.
- chr12:57,194,504–57,226,449, 2 genes (within-gene range 0–2): MIR1228, NXPH4.
- chr14:104,085,686–104,180,894, 5 genes: ASPG, MIR203A, MIR203B, AL359399.1, KIF26A.
- chr15:25,170,723–25,225,284, 30 genes (within-gene range 0–1): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:41,774,434–41,894,053, 8 genes (within-gene range 0–1): MAPKBP1, AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr15:67,819,704–67,873,866, 4 genes: SKOR1, AC009292.2, AC009292.1, RNU6-1.
- chr17:2,680,958–2,688,960, 3 genes (within-gene range 0–1): RN7SL608P, AC005696.2, AC005696.3.
- chr17:16,438,767–16,492,193, 6 genes (within-gene range 0–1): SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr20:63,974,116–63,980,008, 1 gene (within-gene range 0–1): SAMD10.
- chr22:19,171,395–19,178,739, 2 genes: LINC01311, SLC25A1.
- chr22:29,720,003–29,767,011, 3 genes (within-gene range 0–3): CABP7, ZMAT5, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 48 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:52,153,864–53,037,898, 48 genes, copy number 5 (within-gene range 4–21): ZNF836, AC010320.1, PPP2R1A, MIR6801, AC010320.2, AC010320.5, Y_RNA, ZNF766, MIR643, AC010320.3, ZNF480, AC010320.4, ZNF610, ZNF880, ZNF528-AS1, AC010332.1, ZNF528, DPPA5P1, ZNF534, ZNF578, AC010332.3, AC010332.2, AC022150.3, ZNF808, ZNF701, RPL39P34, AC022150.1, ZNF137P, ZNF83, AC022150.2, AC022150.4, ZNF611, ZNF600, ZNF28, PABPN1P2, ZNF468, ZNF320, AC010487.2, ZNF888, AC010487.1, ZNF321P, ZNF816-ZNF321P, ZNF816, AC010328.3, ZNF702P, AC010328.2, AC010328.1, ERVV-1.

Autosomal genes at a single copy (total copy number 1): 12,122. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
